Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4357, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4357-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Not specified. Tumor configuration: Not specified. Tumor size: 10.0 x 11.0 x 1.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Well differentiated. Extent of invasion: Serosa (visceral peritoneum). Lymph nodes: Not specified. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file f3898436-93fe-469e-a019-c213ab22bdfb (TCGA-BR-4357.951438ED-8001-45E2-BCAC-283088CC4F9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).